Somatic mutation profile of tumor specimen MMRF_1157_3_BM_CD138pos (aliquot MMRF_1157_3_BM_CD138pos_T1_KBS5U_L06509) from MMRF case MMRF_1157, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.8 years (25,484 days).
Specimen MMRF_1157_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0d0c692-a749-4c9d-951e-6e41763a65c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1157_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1157_1_PB_Whole_C1_KHS5U_L13424; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e55b3c23-8929-4714-9d24-306884834c97

The open-access MAF lists 121 somatic variants for this specimen: 54 protein-altering or splice-affecting, 13 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 30, Intron 14, Silent 13, 5'Flank 5, 3'Flank 2, Frame Shift Del 2, 5'UTR 2, Splice Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRB3 | c.3614G>T p.G1205V | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as rs780355361; called by muse, mutect2, varscan2
- DENND5B | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.377); catalogued as rs1291794370; called by muse, mutect2, varscan2
- DTD1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV66281362; called by muse, mutect2, varscan2
- ERCC6 | c.1813C>T p.H605Y | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as rs757008329; called by muse, mutect2
- FBXO7 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 242/366 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99832945; called by muse, mutect2, varscan2
- GNL3 | c.1092T>G p.F364L | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV56477272; called by muse, mutect2
- HARS1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765994836, COSV56907022; called by muse, mutect2, varscan2
- HDGF | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100625709; called by muse, mutect2, varscan2
- IGHV2-70 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372581706; called by muse, varscan2
- IGLL5 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.077); catalogued as rs544778929, COSV73248964, COSV73249402; called by muse, mutect2
- MYOG | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 122/229 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV54096037, COSV99613979; called by muse, mutect2, varscan2
- NCK1 | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 96/186 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56637599; called by muse, mutect2, varscan2
- NIBAN2 | c.1723G>C p.D575H | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104394211; called by muse, mutect2, varscan2
- NTRK3 | c.1645T>A p.F549I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62314694; called by muse, mutect2, varscan2
- PRUNE2 | c.4699G>A p.G1567R | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV100944688; called by muse, mutect2, varscan2
- RANBP6 | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV52388916; called by muse, mutect2, varscan2
- STAP2 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472526108; called by muse, mutect2, varscan2
- SVIL | c.4700G>A p.R1567H (on ENST00000355867 / NM_021738.3; = p.R1141H on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs199941504; called by muse, mutect2, varscan2
- TECTA | c.5672C>T p.T1891M | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as rs200977539; called by muse, mutect2, varscan2
- TGFBR3 | c.1025A>T p.Y342F | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV53021271, COSV53023837, COSV99282542; called by muse, mutect2, varscan2
- ZMYM6 | c.2351A>G p.N784S | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV64120072; called by muse, mutect2, varscan2
- ADPRM | c.865T>G p.F289V | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANTXR1 | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- BHLHA15 | c.263T>G p.M88R | Missense Mutation (SNP) | VAF 75/136 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CCDC168 | c.3940G>C p.G1314R | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- COX10 | c.619A>T p.N207Y | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF16 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAT3 | c.10607A>C p.Y3536S | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPN2 | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECTD1 | c.5335G>A p.D1779N | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGHMBP2 | c.1719G>C p.E573D | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KBTBD12 | c.1184A>T p.K395I | Missense Mutation (SNP) | VAF 165/331 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNIP4 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIAA2026 | c.3866C>A p.T1289N | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT79 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NRK | c.854A>T p.K285M | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLFML2A | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR6C1 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 87/155 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PCDHGA4 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 89/186 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2G5 | c.-10-2A>G | Splice Site (SNP) | VAF 85/202 reads (42%) | called by muse, mutect2, varscan2
- PTPN13 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RPS12 | c.-36G>C | Splice Region (SNP) | VAF 109/268 reads (41%) | called by muse, mutect2, varscan2
- SCAPER | c.2116_2117del p.R706Afs*8 | Frame Shift Del (DEL) | VAF 78/217 reads (36%) | called by pindel, varscan2
- SLC9C2 | c.2353G>C p.V785L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SMARCC1 | c.1411C>A p.L471I | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TFAP2D | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 92/179 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMF1 | c.1659G>T p.E553D | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TNS3 | c.144_148del p.Y49Gfs*10 | Frame Shift Del (DEL) | VAF 64/93 reads (69%) | called by mutect2, pindel, varscan2
- TRPC3 | c.2188A>T p.T730S (on ENST00000379645 / NM_001366479.2; = p.T657S on NM_003305.2) | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- UIMC1 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR90 | c.2286C>G p.S762R | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZC2HC1B | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF443 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 123/230 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ACOT12 | c.591C>T p.H197= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs149420016; called by muse, mutect2, varscan2
- CLCN1 | c.297T>C p.C99= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as rs1364971326; called by muse, mutect2, varscan2
- DAAM1 | c.2382G>A p.V794= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as rs752501031; called by muse, mutect2, varscan2
- DIXDC1 | c.2019A>C p.V673= (on ENST00000440460 / NM_001037954.4; = p.V462= on NM_033425.4) | Silent (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- HKDC1 | c.1218C>T p.L406= | Silent (SNP) | VAF 68/127 reads (54%) | catalogued as COSV63578163; called by muse, mutect2, varscan2
- IGLV3-1 | c.60C>T p.S20= | Silent (SNP) | VAF 62/108 reads (57%) | catalogued as rs577917177; called by muse, varscan2
- NTSR1 | c.144G>A p.A48= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs1419894159, COSV65138422; called by muse, mutect2, varscan2
- PCDHGA9 | c.1911G>A p.A637= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs370856862, COSV53995926; called by muse, mutect2, varscan2
- PHEX | c.978C>G p.L326= | Silent (SNP) | VAF 62/62 reads (100%) | called by muse, mutect2, varscan2
- SEMA6B | c.174C>T p.P58= | Silent (SNP) | VAF 55/103 reads (53%) | catalogued as rs1416147415; called by muse, mutect2, varscan2
- SORBS1 | c.3351G>A p.R1117= | Silent (SNP) | VAF 91/157 reads (58%) | catalogued as rs373494742; called by muse, mutect2, varscan2
- XPNPEP1 | c.1857T>C p.S619= | Silent (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- ZER1 | c.2161C>T p.L721= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- ABCC10 | c.162-362A>G | Intron (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700858 C>T | 3'Flank (SNP) | VAF 94/213 reads (44%) | called by muse, mutect2, varscan2
- ARX | c.*330A>G | 3'UTR (SNP) | VAF 19/20 reads (95%) | called by muse, mutect2, varscan2
- BBX | c.*4766A>C | 3'UTR (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- BRS3 | c.*408A>C | 3'UTR (SNP) | VAF 49/51 reads (96%) | called by muse, mutect2, varscan2
- C1orf21 | c.*8633A>G | 3'UTR (SNP) | VAF 28/67 reads (42%) | catalogued as rs900754966; called by muse, mutect2, varscan2
- CHRAC1 | c.*897T>C | 3'UTR (SNP) | VAF 26/57 reads (46%) | catalogued as rs1237186701; called by mutect2, varscan2
- COA1 | c.-38-352G>A | Intron (SNP) | VAF 6/125 reads (5%) | called by muse, mutect2
- CYP2G1P | n.1081A>G | RNA (SNP) | VAF 6/38 reads (16%) | catalogued as rs1457732370; called by muse, mutect2
- DCAF6 | chr1:167936654 G>A | 5'Flank (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.*2121G>A | 3'UTR (SNP) | VAF 55/117 reads (47%) | catalogued as rs1420240285; called by muse, mutect2, varscan2
- DENND1B | c.*1341A>T | 3'UTR (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2
- DENND1B | c.*1339T>A | 3'UTR (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2
- EDIL3 | c.*326A>T | 3'UTR (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- EWSR1 | c.*26T>C | 3'UTR (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- FAM107A | c.*1152A>T | 3'UTR (SNP) | VAF 13/32 reads (41%) | catalogued as rs7648131; called by muse, varscan2
- FAM126B | c.153+74T>C | Intron (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- FAM133A | c.*2063del | 3'UTR (DEL) | VAF 15/20 reads (75%) | called by mutect2, pindel, varscan2
- FAM177A1 | c.96+115G>C | Intron (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2
- FNDC3A | c.*112T>C | 3'UTR (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- ICE2 | chr15:60479209 A>G | 5'Flank (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- IFT74 | c.*199C>T | 3'UTR (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- IQSEC3 | c.-25C>G | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- KIF25 | c.317+2079C>T | Intron (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- KLRK1 | c.*61C>T | 3'UTR (SNP) | VAF 72/162 reads (44%) | called by muse, mutect2
- MAN1C1 | c.*181C>T | 3'UTR (SNP) | VAF 49/101 reads (49%) | called by muse, mutect2, varscan2
- MECP2 | c.*5418T>G | 3'UTR (SNP) | VAF 48/118 reads (41%) | called by muse, mutect2, varscan2
- MYO1F | c.3+51C>T | Intron (SNP) | VAF 54/95 reads (57%) | called by muse, mutect2, varscan2
- NGLY1 | c.246+57T>C | Intron (SNP) | VAF 97/210 reads (46%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+4034A>T | Intron (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- RAB8B | c.*544A>C | 3'UTR (SNP) | VAF 37/70 reads (53%) | called by muse, mutect2, varscan2
- RBM34 | c.*458G>A | 3'UTR (SNP) | VAF 77/156 reads (49%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158906 C>T | 5'Flank (SNP) | VAF 16/26 reads (62%) | catalogued as rs1454104233; called by muse, mutect2, varscan2
- RTKN | c.111+2025A>T | Intron (SNP) | VAF 96/189 reads (51%) | called by muse, mutect2, varscan2
- SCUBE2 | c.256+27G>C | Intron (SNP) | VAF 89/212 reads (42%) | called by muse, mutect2, varscan2
- SGK1 | chr6:134175582 G>A | 5'Flank (SNP) | VAF 42/68 reads (62%) | called by muse, mutect2, varscan2
- SLC32A1 | c.-221G>A | 5'UTR (SNP) | VAF 5/42 reads (12%) | catalogued as COSV54145499; called by muse, varscan2
- SLC39A13 | c.415+25C>T | Intron (SNP) | VAF 21/51 reads (41%) | catalogued as rs1289520959; called by muse, mutect2, varscan2
- SLC39A8 | c.-253-120_-253-119insT | Intron (INS) | VAF 59/154 reads (38%) | called by mutect2, pindel, varscan2
- SLC7A2 | c.*3142G>A | 3'UTR (SNP) | VAF 73/166 reads (44%) | catalogued as rs1391205085; called by muse, mutect2, varscan2
- STPG4 | c.519+822C>T | Intron (SNP) | VAF 16/38 reads (42%) | catalogued as rs1189702710; called by muse, mutect2, varscan2
- TBL1XR1 | c.*5871T>G | 3'UTR (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- TBR1 | c.*7C>T | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2
- TERT | c.2843+39T>C | Intron (SNP) | VAF 27/54 reads (50%) | called by mutect2, varscan2
- TRAF3 | c.*2673G>A | 3'UTR (SNP) | VAF 66/132 reads (50%) | catalogued as rs1019393679; called by muse, mutect2, varscan2
- UAP1L1 | chr9:137086446 C>T | 3'Flank (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- UBN1 | chr16:4847451 G>C | 5'Flank (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- VGLL3 | c.*3186A>T | 3'UTR (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- VGLL3 | c.*1250T>C | 3'UTR (SNP) | VAF 25/42 reads (60%) | called by muse, varscan2
- WDR36 | c.*1340G>C | 3'UTR (SNP) | VAF 56/98 reads (57%) | called by muse, mutect2, varscan2
- YWHAB | c.*1561G>A | 3'UTR (SNP) | VAF 39/87 reads (45%) | catalogued as rs1050666548; called by muse, mutect2, varscan2
- ZDHHC18 | c.*581G>T | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- ZNF398 | c.*3193A>G | 3'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- ZNF641 | c.*1313G>C | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
